Somatic mutation profile of tumor specimen ca14c6dd-2069-4bc5-b1f2-6f2297 (aliquot ca14c6dd-2069-4bc5-b1f2-6f2297_D8) from CPTAC case 14BR008, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.0 years (24,089 days).
Specimen ca14c6dd-2069-4bc5-b1f2-6f2297: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 457e4ecb-8ca4-492e-9af6-91c07724f6cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5d7892a4-966e-44e4-b4d1-83173f (Blood Derived Normal), aliquot 5d7892a4-966e-44e4-b4d1-83173f_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bad68572-352b-4b1e-828e-0e443b2cc560

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Del 3, Intron 3, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3203dup p.N1068Kfs*5 | Frame Shift Ins (INS) | VAF 25/148 reads (17%) | catalogued as rs587776802; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OR8K3 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 34/221 reads (15%) | catalogued as rs142978123; called by muse, mutect2, varscan2
- TEX264 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.92); catalogued as rs762481142; called by muse, mutect2, varscan2
- TRMT12 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776553; called by muse, mutect2, varscan2
- TTN | c.33250G>A p.E11084K (on ENST00000591111; = p.E10157K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/271 reads (17%) | PolyPhen benign (0.361); catalogued as rs765827814, COSV59915823; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- ACACA | c.932_944del p.F311Sfs*2 | Frame Shift Del (DEL) | VAF 48/312 reads (15%) | called by mutect2, pindel, varscan2
- AL121899.2 | c.1504A>C p.I502L | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- CDH1 | c.1450_1463del p.P484Sfs*2 | Frame Shift Del (DEL) | VAF 39/223 reads (17%) | called by mutect2, pindel, varscan2
- MORN4 | c.70_76del p.R24Mfs*6 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- NEDD4L | c.299C>G p.T100R | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR11H2 | c.125C>A p.T42N (on ENST00000556246; = p.T53N on NM_001197287.1) | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PPIG | c.1786C>A p.Q596K | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK1 | c.1788G>T p.K596N | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- TRIP11 | c.3204dup p.Q1069Tfs*6 | Frame Shift Ins (INS) | VAF 68/384 reads (18%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.3105G>A p.A1035= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs772799963, COSV99136413; called by muse, mutect2, varscan2
- CDH4 | c.633C>T p.G211= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs527795069, COSV64647771; called by muse, mutect2, varscan2
- NRP2 | c.2172C>T p.G724= | Silent (SNP) | VAF 58/298 reads (19%) | catalogued as rs747984060; called by muse, mutect2, varscan2
- PLK1 | c.219G>A p.A73= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as COSV100267454, COSV55621101; called by muse, mutect2, varscan2
- ILK | c.448+34C>A | Intron (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- ILK | c.448+35G>A | Intron (SNP) | VAF 28/394 reads (7%) | catalogued as rs758274258; called by muse, mutect2
- SORD | c.67-4055_67-4053del | Intron (DEL) | VAF 17/94 reads (18%) | called by pindel, varscan2
